Somatic mutation profile of tumor specimen TCGA-BR-4257-01A (aliquot TCGA-BR-4257-01A-01D-1126-08) from TCGA case TCGA-BR-4257, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 79.4 years (29,014 days).
Specimen TCGA-BR-4257-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0cc9559-bf0f-4749-bea5-a9e15d319a9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4257-11A (Solid Tissue Normal), aliquot TCGA-BR-4257-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92e373d1-ce39-4ef5-829e-59e4aad39af1

The open-access MAF lists 1,315 somatic variants for this specimen: 963 protein-altering or splice-affecting, 325 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 638, Silent 325, Frame Shift Del 222, Frame Shift Ins 34, Nonsense Mutation 33, Intron 17, Splice Site 15, Splice Region 9, In Frame Del 8, RNA 5, 3'UTR 3, Translation Start Site 3.

Variants (750 of 1,315; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309del p.D1104Mfs*214 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDKL5 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 60/162 reads (37%) | catalogued as rs1057518203, COSV66113281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57246789; called by muse, mutect2, varscan2
- GNPTAB | c.2249del p.N750Ifs*4 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs281864991; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- AADAT | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs768749259, COSV61788126; called by muse, mutect2, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- ABCA10 | c.2639G>T p.R880I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52229636; called by muse, mutect2
- ABCC2 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs767088436, COSV64971334; called by muse, mutect2, varscan2
- AC126283.2 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs371432629, CM135394; ClinVar: risk factor; called by muse, mutect2, varscan2
- ACADL | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1319500123, COSV52055319; called by muse, mutect2, varscan2
- ACP2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs1388226509, COSV57040775; called by muse, mutect2, varscan2
- ACSM1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs767708956, COSV54640091; called by muse, mutect2, varscan2
- ADAM33 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779669835, COSV62936880; called by muse, mutect2, varscan2
- ADAM9 | c.1339T>C p.C447R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65962436; called by muse, mutect2, varscan2
- ADAMTS1 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53173383; called by muse, mutect2, varscan2
- ADAMTS13 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63021706; called by mutect2, varscan2
- ADAMTS6 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV66859444; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1832del p.P611Qfs*13 | Frame Shift Del (DEL) | VAF 35/198 reads (18%) | catalogued as rs1219204735; called by mutect2, pindel, varscan2
- ADAR | c.3603del p.G1202Afs*2 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as CD052083; called by mutect2, pindel, varscan2
- ADCY7 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54266811, COSV54270760; called by muse, mutect2, varscan2
- ADCY9 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as COSV53581769; called by muse, mutect2, varscan2
- ADCY9 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53578756; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.4433G>A p.R1478Q (on ENST00000373658 / NM_001364857.2; = p.R1477Q on NM_001294335.2) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766172504, COSV57070105; called by muse, mutect2
- ADGRB3 | c.4479G>T p.K1493N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV53256207, COSV53259844; called by muse, mutect2, varscan2
- ADRA1A | c.779G>T p.R260M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52373599; called by muse, mutect2, varscan2
- ADTRP | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.233); catalogued as COSV57645758; called by muse, mutect2, varscan2
- AFDN | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs779343002, COSV60056669; called by mutect2, varscan2
- AGFG2 | c.425_427del p.K142del | In Frame Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs1295978762; called by pindel, varscan2
- AGO1 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV64596510; called by muse, mutect2, varscan2
- AKAP10 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV56733084; called by muse, mutect2, varscan2
- AKAP9 | c.3245C>T p.S1082L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV62357740; called by muse, mutect2, varscan2
- ALDH3A1 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV56736855; called by muse, mutect2, varscan2
- ALPP | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67398006; called by muse, mutect2, varscan2
- ALX4 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61328942; called by muse, mutect2, varscan2
- AMACR | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs770694101, COSV59461256; called by muse, mutect2, varscan2
- ANAPC1 | c.4919G>A p.G1640D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs533459247; called by mutect2, varscan2
- ANGPT4 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1041399657, COSV67922833; called by muse, mutect2, varscan2
- ANK3 | c.3001C>T p.R1001C (on ENST00000280772 / NM_001320874.2; = p.R135C on NM_001149.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372646492; called by muse, mutect2, varscan2
- ANKRD39 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs771218314, COSV58412697; called by mutect2, varscan2
- ANKS1A | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64464543; called by muse, mutect2, varscan2
- ANO1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as rs778999525, COSV60284006; called by muse, mutect2, varscan2
- ANO1 | c.2273T>G p.I758S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62449819; called by muse, mutect2, varscan2
- APAF1 | c.2111G>A p.C704Y (on ENST00000551964 / NM_181861.2; = p.C693Y on NM_001160.3) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.807); catalogued as rs1277747453, COSV59668407; called by muse, mutect2, varscan2
- API5 | c.1279-1G>T p.X427_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as COSV66635122; called by muse, mutect2, varscan2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs3215969; called by mutect2, pindel, varscan2
- AREL1 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62668039; called by muse, mutect2, varscan2
- ARFGEF1 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs367687566; called by mutect2, varscan2
- ARHGAP18 | c.488del p.N163Tfs*55 | Frame Shift Del (DEL) | VAF 14/127 reads (11%) | catalogued as rs749346165; called by mutect2, varscan2
- ARHGEF11 | c.3975A>G p.K1325= | Splice Region (SNP) | VAF 13/114 reads (11%) | catalogued as COSV59358549; called by muse, mutect2, varscan2
- ART4 | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57453249; called by muse, mutect2, varscan2
- ASH1L | c.7193A>G p.N2398S (on ENST00000368346 / NM_001366177.2; = p.N2393S on NM_018489.3) | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV64207216; called by muse, mutect2, varscan2
- ASIC3 | c.813+2T>C p.X271_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV52525782; called by muse, mutect2, varscan2
- ASTL | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs200161060, COSV60905073; called by muse, mutect2, varscan2
- ATAD2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749840287, COSV54885283; called by muse, mutect2, varscan2
- ATAD3A | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV59235816; called by muse, mutect2, varscan2
- ATP10A | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATP12A | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs149324896; called by muse, mutect2, varscan2
- ATP2B2 | c.2605C>T p.Q869* (on ENST00000352432; = p.Q835* on NM_001683.5) | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV59507280; called by muse, mutect2, varscan2
- ATP8B1 | c.2187G>C p.W729C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52180177; called by muse, varscan2
- AVEN | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV60736046; called by muse, mutect2, varscan2
- AXIN1 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867213399, COSV51993234; called by muse, mutect2, varscan2
- B3GNT4 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765802851, COSV57336597; called by muse, mutect2, varscan2
- BAHCC1 | c.7789C>T p.R2597C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57033110; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768990780, COSV50060727; called by muse, mutect2, varscan2
- BAIAP3 | c.1833C>A p.C611* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV50105426; called by muse, mutect2, varscan2
- BAP1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56240541; called by muse, mutect2
- BCAN | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61259170; called by muse, mutect2, varscan2
- BEND3 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as COSV64682271; called by muse, mutect2, varscan2
- BIRC2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs531296011, COSV57163124; called by muse, mutect2, varscan2
- BMP4 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55417269; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 42/86 reads (49%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMPR2 | c.2485A>G p.T829A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65813445; called by muse, mutect2, varscan2
- BORA | c.1738G>T p.G580* (on ENST00000613797; = p.G505* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV64697234; called by muse, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.6869C>T p.A2290V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs575208090, COSV56527153; called by muse, mutect2, varscan2
- BTBD10 | c.808A>G p.S270G | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV53401580; called by muse, mutect2, varscan2
- BTBD8 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1240633547, COSV61547736; called by muse, mutect2, varscan2
- BTBD9 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58430979; called by muse, mutect2, varscan2
- BTF3L4 | c.429A>G p.P143= | Splice Region (SNP) | VAF 17/35 reads (49%) | catalogued as COSV57631197; called by muse, mutect2, varscan2
- BTRC | c.1400G>A p.R467Q (on ENST00000370187 / NM_033637.4; = p.R431Q on NM_003939.5) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100927901; called by muse, mutect2, varscan2
- BUB3 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64364239; called by muse, mutect2, varscan2
- C2CD2L | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as rs1471945759, COSV60884775; called by muse, mutect2, varscan2
- C3orf20 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs528361765, COSV53789289; called by muse, mutect2, varscan2
- C8A | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63486404; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs760298114; called by mutect2, pindel
- CACNA1S | c.238_240del p.N80del | In Frame Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs775230434; called by pindel, varscan2
- CAPG | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs185763147, COSV55708808; called by muse, mutect2, varscan2
- CARD10 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs772945473, COSV52659980; called by muse, mutect2, varscan2
- CASKIN1 | c.191T>C p.L64S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58876816; called by muse, mutect2, varscan2
- CATSPERD | c.616del p.S206Lfs*9 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as COSV101062735; called by mutect2, pindel, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs780649799; called by mutect2, varscan2
- CCAR2 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV57907904; called by muse, mutect2, varscan2
- CCAR2 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52386547; called by muse, mutect2, varscan2
- CCDC113 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.493); catalogued as rs776159355, COSV54687841; called by muse, mutect2, varscan2
- CCDC18 | c.2408C>G p.T803R (on ENST00000343253 / NM_001306076.1; = p.T804R on NM_206886.4) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58147652; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC198 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53603530; called by muse, mutect2, varscan2
- CCDC38 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60184974; called by muse, mutect2, varscan2
- CCDC60 | c.90+1G>C p.X30_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as rs574771394, COSV59550326; called by muse, mutect2, varscan2
- CCDC90B | c.593del p.K198Rfs*23 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs753456737; called by mutect2, pindel, varscan2
- CCN2 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63467018; called by muse, varscan2
- CCR2 | c.72del p.F24Lfs*14 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | catalogued as rs1335660200, COSV52749499; called by mutect2, pindel, varscan2
- CD244 | c.922A>G p.T308A (on ENST00000368033 / NM_001166663.2; = p.T303A on NM_016382.4) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs754083936, COSV100458107, COSV59241549; called by muse, mutect2, varscan2
- CD2AP | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV63762990; called by muse, mutect2, varscan2
- CD300LF | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as COSV56899119; called by muse, mutect2, varscan2
- CDC37 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs1302729807, COSV55769832, COSV55770154; called by muse, mutect2, varscan2
- CDC42EP3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99767963; called by muse, mutect2, varscan2
- CDCA7 | c.448C>A p.P150T (on ENST00000347703 / NM_145810.3; = p.P229T on NM_031942.5) | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV60721804; called by muse, mutect2, varscan2
- CDH12 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777335173, COSV66446878; called by muse, mutect2, varscan2
- CDH13 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51867411; called by muse, mutect2, varscan2
- CDH18 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV56959974; called by muse, mutect2, varscan2
- CDH20 | c.2011G>A p.G671S | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs928327481, COSV53017874; called by muse, mutect2, varscan2
- CDH23 | c.5675C>T p.A1892V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs370004432; called by muse, mutect2, varscan2
- CECR2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52847961; called by muse, mutect2, varscan2
- CENPS | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as rs766537484, COSV58364613; called by muse, mutect2, varscan2
- CEP170 | c.4144G>A p.G1382S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs527444882, COSV60514629; called by muse, mutect2, varscan2
- CEP19 | c.130+2T>C p.X44_splice | Splice Site (SNP) | VAF 18/93 reads (19%) | catalogued as COSV56361354; called by muse, mutect2, varscan2
- CEP290 | c.5338G>A p.V1780I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.083); catalogued as rs368492668; ClinVar: uncertain significance; called by mutect2, varscan2
- CEP68 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs528296468, COSV53127530; called by muse, mutect2, varscan2
- CEP72 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs760351806, COSV53797011; called by muse, mutect2, varscan2
- CERCAM | c.559del p.Q187Rfs*84 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs780407630, COSV65712087; called by mutect2, pindel, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHD1 | c.629del p.K210Rfs*39 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as COSV52337505; called by mutect2, pindel, varscan2
- CHD4 | c.5239T>C p.Y1747H (on ENST00000357008 / NM_001363606.2; = p.Y1758H on NM_001273.5) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58910581; called by muse, mutect2, varscan2
- CHIT1 | c.254_256del p.K85del | In Frame Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs777281913; called by pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs368785360; called by muse, mutect2, varscan2
- CIDEA | c.403A>G p.R135G | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs747079058, COSV57600720; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as rs761731080; called by mutect2, varscan2
- CLCN6 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56743025; called by muse, mutect2, varscan2
- CLDN16 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53229305; called by muse, mutect2, varscan2
- CLPTM1L | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as rs769044531, COSV57992877; called by muse, mutect2, varscan2
- CLVS2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV51568889; called by muse, mutect2, varscan2
- CMAS | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57557529; called by muse, mutect2, varscan2
- CMTR1 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV65091699; called by muse, mutect2
- CNDP2 | c.493A>G p.M165V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60841652; called by muse, mutect2, varscan2
- CNOT10 | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59395184; called by muse, mutect2, varscan2
- CNOT10 | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 76/461 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59395200; called by muse, mutect2, varscan2
- CNPY3 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV65710052; called by muse, mutect2, varscan2
- COL14A1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867348400, COSV52868086; called by muse, mutect2, varscan2
- COL4A1 | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1026987399, CM1314306, COSV65431932; called by muse, mutect2
- COL4A2 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs771559117, COSV64631114; called by mutect2, varscan2
- COL4A4 | c.4064G>T p.G1355V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636486; called by muse, mutect2, varscan2
- COL6A3 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs776270797, COSV55083449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2987T>A p.I996N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV62037215; called by muse, varscan2
- COL6A6 | c.4189A>G p.M1397V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62037226; called by muse, mutect2, varscan2
- COL6A6 | c.4879G>T p.G1627* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV62037247; called by muse, mutect2, varscan2
- COL9A3 | c.1548G>T p.P516= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as COSV58983097, COSV58983447, COSV58987178; called by muse, mutect2, varscan2
- COTL1 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV52291703; called by muse, mutect2, varscan2
- CPA4 | c.60del p.K20Nfs*8 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as COSV55979976; called by mutect2, pindel, varscan2
- CPA4 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55985001; called by muse, mutect2
- CR1 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1206948700, COSV65463115; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 32/174 reads (18%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRISPLD2 | c.984G>A p.S328= | Splice Region (SNP) | VAF 19/80 reads (24%) | catalogued as rs779433800, COSV52283083; called by muse, mutect2, varscan2
- CRNN | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as COSV55123828, COSV99663828; called by muse, mutect2, varscan2
- CRTAP | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs772985152, COSV58015019; called by muse, mutect2, varscan2
- CRX | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370592248; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1310-2A>G p.X437_splice | Splice Site (SNP) | VAF 42/99 reads (42%) | catalogued as COSV100175437; called by muse, mutect2, varscan2
- CSMD1 | c.5813T>C p.L1938P (on ENST00000520002; = p.L1937P on NM_033225.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59381669; called by muse, mutect2, varscan2
- CSMD2 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); catalogued as COSV53961035; called by muse, mutect2, varscan2
- CSMD3 | c.7681C>T p.R2561W (on ENST00000297405 / NM_001363185.1; = p.R2457W on NM_052900.3) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756318986, COSV52243175; called by muse, mutect2, varscan2
- CSRNP3 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs780475592, COSV104405571, COSV58776888; called by muse, mutect2, varscan2
- CST11 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100776871, COSV100776873; called by muse, mutect2, varscan2
- CUBN | c.8755+1G>A p.X2919_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as rs775045830, COSV64721662; called by muse, mutect2, varscan2
- CUL1 | c.1516C>A p.R506S | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100296875; called by muse, mutect2, varscan2
- CUL1 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV57390384; called by muse, mutect2, varscan2
- CWC15 | c.654A>T p.E218D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0.372); catalogued as COSV54412492; called by muse, mutect2, varscan2
- CXXC1 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV53276824; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs745836350; called by mutect2, varscan2
- CYRIB | c.713+1G>A p.X238_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV67831333; called by muse, mutect2, varscan2
- DCAF6 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV56583715; called by muse, mutect2, varscan2
- DDI1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs879486728, COSV56374380; called by muse, mutect2, varscan2
- DDX19B | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55362497, COSV55366275; called by muse, varscan2
- DDX42 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs373400646; called by muse, mutect2, varscan2
- DDX55 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs759637997, COSV53017616; called by muse, mutect2, varscan2
- DDX59 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1345946219, COSV58754209; called by muse, mutect2, varscan2
- DEFB119 | c.253T>C p.*85Rext*? | Nonstop Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV53621587; called by muse, mutect2, varscan2
- DEPDC5 | c.2353G>A p.V785M (on ENST00000400246; = p.V854M on NM_014662.5) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56710545; called by muse, mutect2, varscan2
- DESI1 | c.179dup p.G62Rfs*12 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | catalogued as rs772952216; called by mutect2, pindel, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | catalogued as rs748318989; called by mutect2, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX16 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV64565636; called by muse, mutect2, varscan2
- DHX35 | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV52674381; called by muse, mutect2, varscan2
- DHX36 | c.1640T>A p.I547K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57677201; called by muse, mutect2, varscan2
- DIAPH1 | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52767820; called by muse, mutect2, varscan2
- DIAPH3 | c.2770C>T p.Q924* (on ENST00000400324 / NM_001042517.2; = p.Q661* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV57380795, COSV99934501; called by muse, mutect2, varscan2
- DIDO1 | c.6296C>A p.P2099Q | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.339); catalogued as COSV56633706; called by muse, mutect2, varscan2
- DIDO1 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.386); catalogued as COSV56629074; called by muse, mutect2, varscan2
- DIMT1 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV52234917; called by muse, mutect2, varscan2
- DLG1 | c.718G>T p.G240* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV58391260; called by muse, mutect2, varscan2
- DLG5 | c.4442del p.P1481Qfs*88 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs778796396, CM066561; called by mutect2, pindel, varscan2
- DLGAP4 | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs752019701, COSV59417137; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH3 | c.5359C>T p.R1787C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146173789; called by muse, mutect2, varscan2
- DNAH9 | c.12440C>T p.A4147V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52376274; called by muse, mutect2, varscan2
- DNAJB12 | c.136A>G p.I46V (on ENST00000338820; = p.I12V on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV58761718; called by mutect2, varscan2
- DNAJC25-GNG10 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs776244288, COSV65349873; called by muse, mutect2, varscan2
- DNAJC6 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54781549; called by muse, mutect2, varscan2
- DOCK1 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54759645; called by muse, mutect2, varscan2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 48/99 reads (48%) | catalogued as rs1559599687; called by mutect2, pindel, varscan2
- DOCK2 | c.4091G>A p.R1364H | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769663046, COSV56946543, COSV56987375; called by muse, mutect2, varscan2
- DPF1 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV62793880; called by muse, mutect2, varscan2
- DSCC1 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs541414061, COSV58088169; called by muse, mutect2, varscan2
- DSTYK | c.2702T>C p.I901T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.707); catalogued as COSV65688429; called by muse, mutect2, varscan2
- DTNBP1 | c.779_781del p.G260del | In Frame Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs760628074; called by pindel, varscan2
- DTX3L | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs1440193364, COSV56145478; called by muse, mutect2, varscan2
- DYNLT1 | c.45_47del p.D15del | In Frame Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs751911441; called by pindel, varscan2
- ECT2 | c.1409T>C p.I470T (on ENST00000392692 / NM_001349098.2; = p.I439T on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51694034; called by muse, mutect2, varscan2
- EDC4 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54647430; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1711G>A p.V571I (on ENST00000361735 / NM_015935.5; = p.V485I on NM_014955.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.422); catalogued as COSV62283810; called by muse, mutect2, varscan2
- EFNA5 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60957657; called by muse, mutect2, varscan2
- EFTUD2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.727); catalogued as rs1219000676, COSV68184832; called by muse, mutect2, varscan2
- EGFLAM | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs760762744, COSV100469640, COSV59304669; called by mutect2, varscan2
- EGR3 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.793); catalogued as COSV57834476; called by muse, mutect2, varscan2
- EIF2AK3 | c.1067T>A p.F356Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV57552087; called by muse, mutect2, varscan2
- EIF2AK4 | c.4892del p.K1631Rfs*48 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs1400253542; called by mutect2, pindel, varscan2
- EIF4E1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs1296660855, COSV53781927; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs769175197; called by mutect2, varscan2
- ELOA2 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.6); catalogued as COSV55308374, COSV55309189; called by muse, mutect2, varscan2
- ELP6 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs200718652, COSV56133189; called by muse, mutect2, varscan2
- ENPP2 | c.1486A>G p.K496E (on ENST00000075322 / NM_001040092.3; = p.K548E on NM_006209.5) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV50038350; called by muse, mutect2, varscan2
- EPB41L3 | c.2973G>T p.Q991H | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV59467571; called by muse, mutect2, varscan2
- EPB41L4A | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs374814626; called by muse, mutect2, varscan2
- EPHB1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV67671272; called by muse, mutect2, varscan2
- ERBB4 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61522004; called by muse, mutect2, varscan2
- ERI1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1217629171, COSV51572715; called by muse, mutect2, varscan2
- ERICH6 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.266); catalogued as rs374844031, COSV55803237; called by muse, mutect2, varscan2
- ESR2 | c.519del p.F173Lfs*43 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | catalogued as COSV50833811; called by mutect2, pindel, varscan2
- ESRP1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412636; called by muse, varscan2
- EVC | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs147280107; called by muse, mutect2, varscan2
- EVPL | c.4541C>T p.S1514L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1288792258, COSV56909246; called by muse, mutect2, varscan2
- EXOC6 | c.1774-1G>T p.X592_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV53332425; called by muse, mutect2, varscan2
- EXT1 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.277); catalogued as rs1388996809, COSV65484872; called by muse, mutect2, varscan2
- F9 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV54382366, COSV99496251; called by muse, mutect2, varscan2
- FAM110B | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.243); catalogued as COSV64068041; called by muse, mutect2, varscan2
- FAM171A1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs757735986, COSV65317917; called by mutect2, varscan2
- FAM186B | c.2606del p.K869Rfs*11 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs768823856; called by pindel, varscan2
- FAM214B | c.440del p.P147Hfs*50 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV59715297; called by mutect2, pindel, varscan2
- FAM83D | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54159198; called by muse, mutect2
- FAM83F | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754481227, COSV61000108; called by muse, mutect2, varscan2
- FAN1 | c.2810del p.G937Afs*52 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs1566932191; called by mutect2, pindel, varscan2
- FAR1 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1411991716, COSV61386404; called by muse, mutect2, varscan2
- FAT1 | c.7439T>C p.V2480A | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV71675977; called by muse, mutect2
- FAT3 | c.3283G>A p.D1095N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs774427780, COSV53075705; called by muse, mutect2, varscan2
- FAT4 | c.11078G>T p.S3693I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV58708282; called by muse, mutect2, varscan2
- FAXC | c.828T>A p.D276E | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.082); catalogued as COSV67603397, COSV67603767; called by muse, varscan2
- FBN1 | c.5562A>C p.Q1854H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV57322435, COSV57330130; called by mutect2, varscan2
- FBXL4 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs369518305, COSV57750425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO44 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750005384, COSV52355532; called by muse, mutect2, varscan2
- FECH | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055019947, CM980743, COSV50492818; called by muse, mutect2, varscan2
- FGD5 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1170549879, COSV53239489, COSV99547128; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs749851531; called by pindel, varscan2
- FLNC | c.1374del p.I459Sfs*33 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs1360167769; called by mutect2, pindel, varscan2
- FLRT2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766170020, COSV100420725, COSV58149961; called by muse, mutect2, varscan2
- FLRT3 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53989708; called by muse, mutect2, varscan2
- FMNL2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV56504392; called by muse, mutect2, varscan2
- FMOD | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.417); catalogued as rs1430016322, COSV61610588; called by muse, mutect2, varscan2
- FN1 | c.4004T>C p.V1335A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.168); catalogued as rs1456663635, COSV60545915; called by muse, mutect2, varscan2
- FOSB | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62279137; called by muse, mutect2, varscan2
- FOXG1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398945; called by muse, varscan2
- FOXK2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58882870; called by muse, mutect2, varscan2
- FOXO3 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100670102; called by muse, mutect2, varscan2
- FOXP2 | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV63493827; called by muse, mutect2, varscan2
- FRYL | c.5440C>A p.L1814M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51962067; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs756304971; called by mutect2, varscan2
- FYB2 | c.387del p.V130* | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as COSV100599468; called by mutect2, pindel, varscan2
- G3BP2 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100693021, COSV62977628; called by muse, mutect2, varscan2
- GABRG2 | c.1072C>A p.L358I (on ENST00000361925 / NM_001375343.1; = p.L318I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62722508; called by muse, mutect2, varscan2
- GAMT | c.526del p.E176Sfs*2 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as CD0911438; called by mutect2, pindel, varscan2
- GAS6 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs776678863, COSV59855742; called by muse, mutect2, varscan2
- GASK1B | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1348796998, COSV56710400; called by muse, mutect2, varscan2
- GATA4 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs376885265; called by muse, mutect2, varscan2
- GBA | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.181); catalogued as rs11558184, COSV59171011; called by muse, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 69/146 reads (47%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GDF11 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57690619; called by muse, mutect2, varscan2
- GEMIN8 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV60551434; called by muse, mutect2, varscan2
- GIGYF2 | c.1641T>C p.G547= | Splice Region (SNP) | VAF 18/124 reads (15%) | catalogued as COSV65253512; called by muse, mutect2, varscan2
- GIT1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs975963915, COSV56404048; called by muse, mutect2, varscan2
- GJB6 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV53833539; called by muse, mutect2, varscan2
- GNAT3 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs768900454, COSV68068684; called by muse, mutect2, varscan2
- GNPDA1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753033449, COSV60942574; called by muse, mutect2, varscan2
- GNRH2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs200702474; called by muse, mutect2, varscan2
- GOLPH3 | c.677T>G p.V226G | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV54062593; called by muse, mutect2, varscan2
- GOT2 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as rs537935734, COSV55333384; called by muse, mutect2, varscan2
- GPD1 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV56547530, COSV56549151; called by muse, mutect2, varscan2
- GPR39 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61417572; called by muse, mutect2, varscan2
- GPRC5B | c.295T>C p.F99L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100315251; called by muse, mutect2
- GRAMD4 | c.1651A>G p.M551V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV63032602; called by muse, mutect2, varscan2
- GRHL1 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61216060; called by muse, varscan2
- GRIK4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as rs200724152; called by muse, mutect2, varscan2
- GRM4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431545411, COSV65210816; called by muse, mutect2, varscan2
- GRM7 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774045497, COSV63170499; called by muse, mutect2
- GRPEL1 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1280670467, COSV53826831; called by muse, mutect2, varscan2
- GSTCD | c.1493C>T p.A498V (on ENST00000360505 / NM_001031720.3; = p.A411V on NM_024751.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV64735658; called by muse, mutect2, varscan2
- GSX1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232666; called by muse, mutect2, varscan2
- GTPBP3 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61414523; called by muse, mutect2
- H4C6 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV100897504; called by muse, varscan2
- HCAR2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1439775894, COSV61024898, COSV61025803; called by muse, mutect2, varscan2
- HDLBP | c.1585C>G p.R529G | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV60496790, COSV60500749; called by muse, mutect2
- HECW1 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67839720; called by muse, mutect2, varscan2
- HEG1 | c.2531C>T p.T844I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV60765527; called by muse, mutect2
- HERC2 | c.9656C>T p.A3219V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746006263, COSV55335187, COSV55337698; called by muse, mutect2, varscan2
- HIRIP3 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54231739; called by muse, mutect2, varscan2
- HIVEP2 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770380783, COSV50059941; called by muse, mutect2, varscan2
- HK3 | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762226493, COSV52844459; called by muse, mutect2, varscan2
- HLA-G | c.621C>T p.D207= | Splice Region (SNP) | VAF 26/129 reads (20%) | catalogued as rs756079304, COSV64406835; called by muse, mutect2, varscan2
- HLF | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1414452352, COSV56831754; called by muse, mutect2, varscan2
- HNF4A | c.724del p.V242Cfs*4 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as CM133280, COSV57380521; called by mutect2, pindel, varscan2
- HOXA5 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56072607; called by muse, mutect2
- HOXD11 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50913031; called by muse, mutect2, varscan2
- HPS1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753635327, COSV57268666; called by muse, mutect2, varscan2
- HRH2 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51576234; called by muse, mutect2, varscan2
- HSD17B4 | c.113T>C p.V38A (on ENST00000414835 / NM_001199291.3; = p.L35= on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); catalogued as COSV56339026; called by muse, mutect2, varscan2
- HSH2D | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372833514, COSV99037481; called by muse, mutect2, varscan2
- HSPA6 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59062575; called by muse, mutect2
- HSPA6 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.498); catalogued as rs1293659614, COSV59063341; called by muse, mutect2, varscan2
- HTR3B | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1048150562, COSV52747629; called by muse, mutect2, varscan2
- IFNA10 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170503295, COSV99497569; called by muse, mutect2, varscan2
- IFNL3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs202143862, COSV69830197; called by mutect2, varscan2
- IFT172 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs752494593, COSV53131580; ClinVar: uncertain significance; called by muse, varscan2
- IGSF8 | c.479del p.P160Qfs*15 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs754902711; called by mutect2, varscan2
- IL27 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs775285948, COSV60490993; called by muse, mutect2, varscan2
- INAVA | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV66257518; called by muse, mutect2, varscan2
- INHBE | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV56988948; called by muse, mutect2, varscan2
- IPCEF1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 38/230 reads (17%) | catalogued as rs754352746, COSV54543358; called by muse, mutect2, varscan2
- IRF2 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66930553; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs780982673; called by mutect2, varscan2
- ISCU | c.167C>T p.S56F (on ENST00000311893 / NM_213595.4; = p.S31F on NM_014301.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV57210604; called by muse, mutect2, varscan2
- ITGA2B | c.1439G>T p.R480I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52235062; called by muse, mutect2, varscan2
- ITGAX | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755857359, COSV51651379; called by muse, mutect2, varscan2
- ITSN2 | c.2669C>A p.P890H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61953903; called by muse, mutect2, varscan2
- JARID2 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59197687; called by muse, mutect2
- JARID2 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV59043871; called by muse, mutect2, varscan2
- JCAD | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs563388639, COSV64758456; called by muse, mutect2, varscan2
- JMJD8 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV50204731; called by muse, mutect2, varscan2
- JSRP1 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV55560746; called by muse, mutect2, varscan2
- KAT6A | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV55911849; called by muse, mutect2, varscan2
- KAT8 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54898873; called by muse, mutect2, varscan2
- KBTBD3 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV73241635; called by muse, mutect2, varscan2
- KCNB1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV65570802; called by muse, mutect2, varscan2
- KCNH7 | c.2245dup p.A749Gfs*3 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | catalogued as rs757276514; called by mutect2, pindel, varscan2
- KCNJ2 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs771965504, CM1511395, COSV54663863; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 26/47 reads (55%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNMA1 | c.1859+2T>C p.X620_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV54286797; called by muse, mutect2, varscan2
- KCNQ2 | c.1955del p.P652Rfs*278 (on ENST00000359125 / NM_172107.4; = p.P624Rfs*278 on NM_004518.6) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as COSV60550914; called by mutect2, pindel, varscan2
- KCNQ3 | c.2469del p.S824Rfs*4 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV101196164; called by mutect2, pindel, varscan2
- KCNV2 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs547033951, COSV66057050; called by muse, mutect2, varscan2
- KIAA1109 | c.9818C>T p.A3273V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.978); catalogued as COSV52691726; called by muse, mutect2, varscan2
- KIF3B | c.1582A>C p.S528R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV65229287; called by muse, mutect2, varscan2
- KLHL2 | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV99900200; called by muse, mutect2, varscan2
- KMT2C | c.6196C>T p.R2066* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as rs1211949081, COSV51437028; called by muse, mutect2, varscan2
- KMT2E | c.1988A>G p.Q663R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV57579604; called by muse, mutect2, varscan2
- KMT2E | c.3427G>A p.D1143N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV57569420; called by muse, mutect2, varscan2
- KPNA5 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV62654720; called by muse, mutect2, varscan2
- KPTN | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV57645848; called by muse, mutect2, varscan2
- KRTAP1-5 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV62624564; called by muse, mutect2, varscan2
- LAMA2 | c.6598C>T p.R2200C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568648664, COSV70346607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC2 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs756385275, COSV51459670; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LAYN | c.277T>C p.F93L (on ENST00000375615 / NM_001258390.1; = p.F85L on NM_178834.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as rs984889362, COSV65105520; called by muse, mutect2, varscan2
- LGMN | c.841A>C p.M281L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV58405206; called by muse, mutect2, varscan2
- LGR5 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV57009923; called by muse, mutect2, varscan2
- LIG4 | c.1475del p.P492Lfs*21 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as rs767195999, COSV63597550; called by mutect2, pindel, varscan2
- LIN9 | c.1369C>T p.R457W (on ENST00000366808 / NM_001270410.2; = p.R402W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752471823, COSV60244820, COSV60247046; called by muse, mutect2, varscan2
- LONP1 | c.2429T>C p.M810T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61502094; called by muse, mutect2, varscan2
- LOX | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs1392323376, COSV50239299; called by muse, mutect2, varscan2
- LRCH4 | c.1179-2A>G p.X393_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV59644573; called by muse, mutect2, varscan2
- LRFN2 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs201054196, COSV57834497, COSV57836717; called by muse, mutect2, varscan2
- LRIG2 | c.2989G>A p.V997M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs374982078; called by muse, mutect2, varscan2
- LRP1B | c.1246C>A p.L416I | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV67273440; called by muse, mutect2, varscan2
- LRP8 | c.2433C>T p.H811= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60101259; called by muse, mutect2, varscan2
- LRRC1 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.669); catalogued as COSV63825194; called by muse, mutect2, varscan2
- LRRC30 | c.7del p.A3? | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs1364391071, COSV101274377; called by mutect2, pindel
- LRRC36 | c.1868T>A p.I623N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs753967980, COSV52082283; called by muse, mutect2, varscan2
- LRRC3B | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV67522664; called by muse, mutect2, varscan2
- LRRC45 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs767623676, COSV60712943; called by muse, mutect2, varscan2
- LRRC8B | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1303430391, COSV58377123; called by muse, mutect2, varscan2
- LRRN1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV60012144; called by muse, mutect2, varscan2
- LSM10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs750020323, COSV59872305; called by muse, mutect2, varscan2
- LSM14A | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV70885692; called by muse, mutect2, varscan2
- LTBP1 | c.5161G>A p.E1721K (on ENST00000404816 / NM_206943.4; = p.E1395K on NM_000627.4) | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as COSV55385241; called by muse, varscan2
- LZTS3 | c.1421G>A p.R474H (on ENST00000329152; = p.R428H on NM_001282533.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1226783307, COSV53909578; called by mutect2, varscan2
- MADD | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV60629708; called by muse, mutect2, varscan2
- MAGI2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs199541452, COSV62678542; called by muse, mutect2, varscan2
- MAGI3 | c.2728T>C p.S910P | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV56844002; called by muse, mutect2, varscan2
- MAML3 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV59077857; called by muse, mutect2, varscan2
- MAPK4 | c.610A>G p.N204D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV68543781; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs747980715, COSV51704302; called by mutect2, pindel, varscan2
- MASP1 | c.551A>C p.E184A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99397562; called by muse, mutect2, varscan2
- MATN3 | c.1376G>T p.S459I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV55606840; called by muse, mutect2, varscan2
- MBD6 | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63076393; called by muse, mutect2, varscan2
- MBOAT1 | c.336dup p.V113Cfs*46 | Frame Shift Ins (INS) | VAF 11/90 reads (12%) | catalogued as rs763568427; called by mutect2, pindel, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM4 | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749728850, COSV50623227; called by muse, mutect2, varscan2
- MCM8 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52545438; called by muse, mutect2, varscan2
- MCTP2 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs536270811, COSV59140535; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs750092100; called by mutect2, varscan2
- MDN1 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1336479642, COSV65530111; called by muse, mutect2, varscan2
- MED12 | c.4556A>G p.Y1519C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV61355193; called by muse, varscan2
- MEGF8 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446825911, COSV52101260; called by muse, mutect2, varscan2
- MEX3C | c.1243A>C p.S415R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV101346312; called by mutect2, varscan2
- MFSD8 | c.558del p.Q187Rfs*12 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs1350716726; called by mutect2, pindel, varscan2
- MGAT4B | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52979717; called by muse, mutect2, varscan2
- MGST3 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | catalogued as rs779960742, COSV63321051; called by muse, mutect2, varscan2
- MICAL2 | c.4690del p.T1564Lfs*76 | Frame Shift Del (DEL) | VAF 39/126 reads (31%) | catalogued as COSV99074660; called by mutect2, pindel, varscan2
- MICALL2 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV52518812; called by muse, mutect2, varscan2
- MICOS13 | c.150del p.A51Pfs*39 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs751944867; called by mutect2, pindel, varscan2
- MICU2 | c.1015A>G p.S339G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV66675478; called by muse, mutect2, varscan2
- MKNK1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57862948; called by muse, mutect2, varscan2
- MLF1 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV63034914; called by muse, varscan2
- MPEG1 | c.1039T>C p.Y347H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs752177032, COSV57092948, COSV57094931; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs145688067; called by muse, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRC1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100509578; called by muse, mutect2, varscan2
- MRPL2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs532734983, COSV52436506; called by muse, mutect2, varscan2
- MS4A10 | c.295dup p.A99Gfs*19 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | catalogued as rs1407636693; called by mutect2, pindel, varscan2
- MSI2 | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV52367922; called by muse, mutect2, varscan2
- MSRA | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57811200; called by muse, mutect2, varscan2
- MTERF2 | c.1110del p.V371* | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs770823090, COSV53527533; called by mutect2, pindel, varscan2
- MTRR | c.478G>A p.V160I (on ENST00000264668; = p.V133I on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as rs770923981, COSV52946789; called by muse, mutect2, varscan2
- MUC16 | c.4472C>T p.P1491L | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs764814054, COSV101201148, COSV67492776; called by muse, mutect2, varscan2
- MYCBP2 | c.10813G>A p.G3605R (on ENST00000357337; = p.G3643R on NM_015057.5) | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62029413; called by muse, mutect2, varscan2
- MYF5 | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV57356575; called by muse, mutect2, varscan2
- MYH2 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs775289093, COSV55433810; called by muse, mutect2, varscan2
- MYH7 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV62523668; called by muse, mutect2, varscan2
- MYH7B | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs952357312, COSV53425396; called by muse, mutect2, varscan2
- MYMK | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60601582; called by muse, mutect2, varscan2
- MYO15A | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs934249137, COSV52761349; called by muse, varscan2
- MYO3B | c.3559G>A p.V1187I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV58717352; called by muse, mutect2, varscan2
- MYO9B | c.2642C>T p.T881I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV68282690; called by muse, mutect2, varscan2
- MYOF | c.5546T>C p.V1849A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63710536; called by muse, mutect2, varscan2
- MYT1 | c.2542G>A p.G848S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs755397766, COSV60513277; called by muse, mutect2
- NAA16 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1227692917, COSV65130151; called by muse, mutect2, varscan2
- NADK | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs965784613, COSV58269172; called by muse, mutect2, varscan2
- NAIP | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs757309016, COSV52001204; called by muse, mutect2, varscan2
- NAP1L1 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99674006; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NASP | c.478del p.T160Qfs*29 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | catalogued as COSV100601638; called by mutect2, pindel, varscan2
- NAV2 | c.2360C>T p.T787M (on ENST00000396087 / NM_001244963.2; = p.T764M on NM_145117.5) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs180786689; called by muse, mutect2, varscan2
- NCAM2 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765685495, COSV53072800; called by muse, mutect2, varscan2
- NCOR2 | c.3904del p.H1302Mfs*12 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as COSV100657106; called by mutect2, pindel, varscan2
- NEFL | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.832); catalogued as rs1563251843, COSV55338447; called by muse, mutect2, varscan2
- NEK3 | c.801del p.E268Rfs*11 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1310043980, COSV99317750; called by mutect2, pindel, varscan2
- NEK5 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200564973; called by muse, mutect2, varscan2
- NEO1 | c.1228T>C p.C410R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56078105; called by muse, mutect2, varscan2
- NFASC | c.3700A>G p.N1234D (on ENST00000339876 / NM_001378329.1; = p.N1163D on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV58379754; called by muse, mutect2, varscan2
- NFKBIB | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs759042553, COSV58005303; called by muse, mutect2, varscan2
- NIBAN2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64825534; called by muse, mutect2, varscan2
- NIN | c.6088G>A p.E2030K (on ENST00000382041 / NM_182946.1; = p.E1317K on NM_016350.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV55379274, COSV55405927; called by muse, mutect2, varscan2
- NIN | c.4950G>A p.Q1650= (on ENST00000382041 / NM_182946.1; = p.Q937= on NM_016350.4) | Splice Region (SNP) | VAF 44/163 reads (27%) | catalogued as rs776581628, COSV55405957, COSV99815026; called by muse, mutect2, varscan2
- NINL | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV54004922; called by muse, mutect2, varscan2
- NLGN4X | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52035902; called by muse, mutect2, varscan2
- NLRC5 | c.3805C>T p.Q1269* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV52651820; called by muse, varscan2
- NMT1 | c.1366A>G p.M456V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51962733; called by muse, mutect2, varscan2
- NNAT | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1568684225, COSV50351511; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOX5 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs373906925, COSV52992960, COSV52997061; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 6/36 reads (17%) | catalogued as rs35747263; called by mutect2, pindel
- NR1H4 | c.1283T>C p.V428A (on ENST00000551379 / NM_001206993.2; = p.V414A on NM_005123.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV51856785; called by muse, mutect2, varscan2
- NR2C1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1224042936, COSV58012238; called by muse, mutect2, varscan2
- NRG1 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV55175659; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP2 | c.1097G>A p.S366N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1292530948, COSV55935309; called by muse, mutect2, varscan2
- NUBP1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51595646; called by muse, mutect2, varscan2
- NUDCD1 | c.1664C>A p.P555H | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); catalogued as COSV53460546; called by muse, mutect2, varscan2
- NUDT11 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV101047100; called by mutect2, varscan2
- NUF2 | c.362del p.L121* | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as COSV54842216; called by mutect2, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- NUP153 | c.3091T>G p.S1031A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV50464901; called by muse, mutect2, varscan2
- NUP160 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV65856035; called by muse, mutect2, varscan2
- NUP210 | c.3142G>A p.G1048S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs541868505, COSV54413869; called by mutect2, varscan2
- NUP98 | c.3727G>A p.V1243I (on ENST00000359171 / NM_001365126.1; = p.V1226I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV61438294; called by muse, mutect2, varscan2
- NUTM1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV59219006; called by muse, mutect2, varscan2
- NVL | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768455674, COSV55876203; called by muse, mutect2, varscan2
- OAF | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs886759316, COSV61109967; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OGFRL1 | c.1035del p.A346Pfs*13 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs1395242573; called by mutect2, pindel, varscan2
- ONECUT1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1230107602, COSV59950812; called by muse, mutect2, varscan2
- OPN5 | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV55247548; called by muse, mutect2, varscan2
- OR11H1 | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99421928; called by mutect2, varscan2
- OR13J1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as rs369145177; called by muse, mutect2, varscan2
- OR2A14 | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV68718658; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR56A4 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1287017320, COSV58111678; called by muse, mutect2, varscan2
- OR5K3 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs748240481, COSV67350695; called by muse, mutect2, varscan2
- OR5T2 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV57588644, COSV57590882; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8B12 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as rs148702196; called by muse, mutect2, varscan2
- OTOF | c.5773G>T p.G1925C (on ENST00000272371 / NM_194248.3; = p.G1158C on NM_004802.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55510848; called by muse, mutect2, varscan2
- OTUD7A | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as COSV61043319; called by muse, mutect2, varscan2
- P2RX2 | c.826G>A p.A276T (on ENST00000343948 / NM_170683.4; = p.A204T on NM_012226.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs200403901, COSV57690389; called by muse, mutect2, varscan2
- P2RX3 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV54444761; called by muse, mutect2, varscan2
- P4HTM | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs768160824, COSV59089099; called by muse, mutect2, varscan2
- PACS2 | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57657202; called by muse, mutect2, varscan2
- PALLD | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778216620, COSV54994537; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PCBP1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV57851884; called by muse, mutect2, varscan2
- PCDH10 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.65); catalogued as rs754653138, COSV52096329, COSV52102015; called by muse, mutect2, varscan2
- PCDHA1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV65376899; called by muse, mutect2, varscan2
- PCDHA10 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV56481497, COSV56544205; called by muse, mutect2, varscan2
- PCDHA11 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56514729; called by muse, mutect2, varscan2
- PCDHA13 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56489611; called by muse, mutect2, varscan2
- PCDHA7 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1480850746, COSV65345107; called by muse, mutect2, varscan2
- PCDHB15 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV51423740; called by muse, mutect2, varscan2
- PCDHGA11 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV54030164; called by muse, mutect2, varscan2
- PCDHGA4 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as rs764054199, COSV53967053; called by muse, mutect2, varscan2
- PCDHGC3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.286); catalogued as COSV52767803; called by muse, mutect2, varscan2
- PCNX1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs751997396, COSV53101708; called by muse, mutect2, varscan2
- PCNX2 | c.6298C>T p.R2100* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs777172938, COSV50889963; called by muse, mutect2, varscan2
- PCNX4 | c.2579A>G p.Q860R (on ENST00000406854 / NM_001330177.2; = p.Q626R on NM_022495.5) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV58308041; called by muse, mutect2, varscan2
- PDCL | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243880809, COSV52343572; called by muse, mutect2, varscan2
- PDCL | c.465del p.Q157Nfs*15 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as rs1347726498; called by mutect2, pindel, varscan2
- PDE5A | c.2557T>C p.W853R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99309050; called by muse, mutect2, varscan2
- PDE5A | c.1099T>C p.C367R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53352809; called by muse, mutect2, varscan2
- PDLIM5 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs761636570, COSV58752727; called by muse, mutect2, varscan2
- PDPR | c.134T>A p.V45E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55356460; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs759495724; called by mutect2, varscan2
- PELI1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV62730874; called by muse, mutect2, varscan2
- PEX6 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV55105466; called by muse, mutect2, varscan2
- PF4V1 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56953884; called by muse, mutect2, varscan2
- PHB2 | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs782262172, COSV54643893; called by muse, mutect2, varscan2
- PHF14 | c.165A>C p.E55D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV68857295; called by muse, mutect2, varscan2
- PHF20L1 | c.1938T>A p.D646E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV99621840; called by muse, mutect2, varscan2
- PHOX2B | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.73); catalogued as COSV56931558; called by muse, mutect2, varscan2
- PHTF1 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs578061932, COSV63367244; called by muse, mutect2, varscan2
- PHTF1 | c.1637dup p.M547Hfs*10 | Frame Shift Ins (INS) | VAF 17/46 reads (37%) | catalogued as rs750248180; called by mutect2, varscan2
- PIAS3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65172091; called by muse, mutect2, varscan2
- PIK3C2B | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV65804220; called by muse, mutect2, varscan2
- PIK3CB | c.1744T>C p.W582R | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56690236; called by muse, mutect2, varscan2
- PITRM1 | c.2971G>T p.E991* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV56539571; called by muse, mutect2, varscan2
- PIWIL4 | c.1709G>A p.C570Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV54412470; called by muse, mutect2
- PLBD2 | c.1511C>A p.A504D | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55108999; called by muse, mutect2, varscan2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG4 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766535968, COSV58575150; called by mutect2, varscan2
- PLG | c.1752del p.C585Vfs*27 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as COSV99071010; called by mutect2, pindel, varscan2
- PLXNB1 | c.3067T>C p.S1023P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV56494128; called by muse, mutect2
- PLXND1 | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753978969, COSV60719297; called by muse, mutect2, varscan2
- POLQ | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as rs779818079, COSV51761134; called by muse, mutect2, varscan2
- POMGNT2 | c.1238del p.G413Afs*53 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs780368344; called by mutect2, pindel, varscan2
- PPEF2 | c.1039T>C p.F347L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV54426207; called by muse, mutect2
- PPP1R10 | c.2808del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as COSV64738548; called by mutect2, pindel
- PPP1R10 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as COSV64739008; called by muse, mutect2, varscan2
- PPP1R16B | c.1160G>T p.R387M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.428); catalogued as COSV55383996; called by muse, mutect2, varscan2
- PPP2R3B | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66814387; called by muse, mutect2, varscan2
- PPP2R3C | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54835076; called by muse, mutect2, varscan2
- PPP2R5E | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61744198; called by muse, mutect2, varscan2
- PRKCH | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV60652380; called by muse, mutect2, varscan2
- PRKN | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs747891099, HM070046, COSV58207384; called by muse, varscan2
- PRPF3 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61396372; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1543C>T p.Q515* (on ENST00000352766; = p.Q436* on NM_181334.5) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs757600105, COSV100424569; called by muse, mutect2, varscan2
- PRSS48 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV71614163; called by muse, mutect2, varscan2
- PSD | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs751241410, COSV50041915; called by muse, mutect2, varscan2
- PSIP1 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.971); catalogued as COSV66253655; called by muse, mutect2, varscan2
- PTBP2 | c.479C>G p.A160G (on ENST00000426398 / NM_001300986.2; = p.A152G on NM_021190.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV64626476; called by muse, mutect2, varscan2
- PTGIS | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV54837378; called by muse, mutect2, varscan2
- PTK2B | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs759650182, COSV57765851; called by muse, mutect2, varscan2
- PTP4A3 | c.428G>A p.S143N (on ENST00000329397; = p.S118N on NM_007079.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as COSV61472813; called by muse, mutect2, varscan2
- PTPN18 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs1188242520, COSV51560702; called by muse, mutect2, varscan2
- PTPN3 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99356117; called by muse, mutect2
- PTPN4 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55309062; called by muse, mutect2, varscan2
- PTPRJ | c.2228C>A p.P743H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69254635; called by muse, mutect2, varscan2
- PTPRR | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51747622; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 39/55 reads (71%) | catalogued as rs754588466; called by mutect2, varscan2
- QTRT2 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV55561790; called by muse, mutect2, varscan2
- RAB1B | c.241dup p.A81Gfs*9 | Frame Shift Ins (INS) | VAF 13/34 reads (38%) | catalogued as rs760802454; called by mutect2, pindel, varscan2
- RABGAP1 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.667); catalogued as COSV65395849; called by muse, mutect2, varscan2
- RAD50 | c.3409A>G p.S1137G | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54757634; called by muse, mutect2, varscan2
- RAG1 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55028131; called by muse, mutect2, varscan2
- RANBP6 | c.2918del p.N973Mfs*12 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs746880803; called by mutect2, varscan2
- RARB | c.268G>A p.V90I (on ENST00000383772 / NM_001290216.2; = p.V83I on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs372338731; called by muse, mutect2, varscan2
- RASAL2 | c.2565A>G p.I855M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV62722983; called by muse, mutect2, varscan2
- RASGEF1A | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs569429774, COSV65666872; called by mutect2, varscan2
- RASSF4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs200147715, COSV53584646; called by muse, mutect2, varscan2
- RBFOX1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60943698, COSV60975947; called by muse, mutect2, varscan2
- RBM25 | c.795T>A p.N265K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1385318628, COSV56202893; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs762006287; called by mutect2, varscan2
- RECQL4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs117670586, COSV52882769; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- REV3L | c.7727A>T p.Y2576F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.414); catalogued as COSV62623361; called by muse, mutect2, varscan2
- REXO4 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.153); catalogued as COSV64242289; called by muse, mutect2, varscan2
- RGL1 | c.1034del p.K345Rfs*12 (on ENST00000360851 / NM_001297672.2; = p.K380Rfs*12 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/121 reads (13%) | catalogued as rs1290470008; called by mutect2, pindel, varscan2
- RGS12 | c.3526A>G p.K1176E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs760916479, COSV58750063; called by muse, mutect2, varscan2
- RGS21 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV101314073; called by muse, mutect2, varscan2
- RHOBTB2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs1280583223, COSV52572948; called by muse, mutect2, varscan2
- RIC8B | c.1402T>G p.S468A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62697093; called by muse, mutect2, varscan2
- RIMS1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753531827, COSV53438444; called by muse, mutect2, varscan2
- RIMS2 | c.1420del p.M474Wfs*5 (on ENST00000666250 / NM_001348490.2; = p.M282Wfs*5 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | catalogued as COSV99213901; called by mutect2, pindel, varscan2
- RNF148 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377391654, COSV57350295; called by muse, mutect2, varscan2
- RNF216 | c.2594G>A p.R865H (on ENST00000425013 / NM_207116.3; = p.R922H on NM_207111.4) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs778491862, COSV66292539; called by muse, mutect2, varscan2
- RO60 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV66474998; called by mutect2, varscan2
- ROS1 | c.5332G>T p.G1778* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV63861550; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.3227A>G p.D1076G | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV64823280; called by muse, mutect2, varscan2
- RPS3A | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1419453482, COSV56839832; called by muse, mutect2, varscan2
- RPTOR | c.2020T>C p.Y674H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs768927275, COSV60818251; called by muse, mutect2, varscan2
- RPTOR | c.2440G>T p.V814F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV60818256; called by muse, mutect2, varscan2
- RTF1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV67477986; called by muse, mutect2, varscan2
- RTN4 | c.2901A>G p.I967M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs199592685, COSV58273783; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as rs761969807; called by mutect2, varscan2
- RTRAF | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs532704605, COSV55564213; called by muse, mutect2, varscan2
- RTTN | c.2687T>C p.V896A | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV55352000; called by muse, mutect2, varscan2
- RUVBL1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs546455182, COSV59477195; called by muse, mutect2, varscan2
- RWDD4 | c.204dup p.N69* | Frame Shift Ins (INS) | VAF 20/59 reads (34%) | catalogued as rs1325913157; called by mutect2, varscan2
- RXFP2 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1466552196, COSV53640941; called by muse, mutect2, varscan2
- RXRB | c.881del p.G294Efs*43 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV59495758, COSV59496898; called by mutect2, pindel, varscan2
- RYR2 | c.6218C>T p.S2073F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV63679042; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs749201569; called by mutect2, varscan2
- SALL4 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53855960; called by muse, varscan2
- SCUBE1 | c.1645A>G p.T549A | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV62616235; called by muse, mutect2, varscan2
- SCYL1 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as rs201604417; called by muse, mutect2, varscan2
- SDE2 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV55252076; called by muse, mutect2, varscan2
- SEC13 | c.636T>G p.S212R (on ENST00000350697 / NM_183352.3; = p.S215R on NM_030673.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61602507; called by muse, mutect2, varscan2
- SEC24C | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV59544891; called by muse, mutect2, varscan2
- SEMA3G | c.1615T>C p.Y539H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51598430; called by muse, mutect2
- SEMA5A | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs140433904, COSV66805261; called by muse, mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SERPINA6 | c.487T>C p.W163R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.073); catalogued as rs376846419; called by muse, mutect2, varscan2
- SERPINB13 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 21/124 reads (17%) | catalogued as rs368306028; called by muse, mutect2, varscan2
- SETBP1 | c.214A>C p.N72H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV56336402; called by muse, mutect2, varscan2
- SGCG | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.86); catalogued as COSV54569126; called by muse, mutect2, varscan2
- SH2D3A | c.341T>G p.V114G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55588659; called by muse, mutect2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs746556543; called by mutect2, varscan2
- SHH | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1563200744, COSV51918305, COSV51918554; called by mutect2, varscan2
- SIGLEC9 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs61739656; called by muse, mutect2, varscan2
- SIM1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs374696271, COSV53492540; called by muse, mutect2, varscan2
- SIPA1L1 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1481909152, COSV62173554; called by muse, mutect2, varscan2
- SIPA1L3 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV55924029; called by muse, mutect2, varscan2
- SIX3 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV53228690; called by muse, mutect2
- SKIV2L | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.138); catalogued as rs867606706, COSV64814131; called by muse, mutect2, varscan2
- SLAMF7 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV63564089; called by muse, mutect2
- SLC14A2 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs151319242, COSV54913520; called by muse, mutect2, varscan2
- SLC22A11 | c.7T>C p.F3L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57255037; called by muse, mutect2, varscan2
- SLC24A1 | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760183851, COSV56051315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A17 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs372825776; called by muse, mutect2, varscan2
- SLC29A4 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs769279731, COSV51876824; called by muse, mutect2, varscan2
- SLC37A3 | c.701T>A p.I234N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58268506; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A7 | c.1654T>C p.F552L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1240960604, COSV55402682; called by muse, mutect2, varscan2
- SLC4A7 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1559722353, COSV55402704; called by muse, mutect2, varscan2
- SLC52A2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.37); catalogued as rs781928955, COSV57352133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A5 | c.2302del p.E768Sfs*6 | Frame Shift Del (DEL) | VAF 31/90 reads (34%) | catalogued as CM064281; called by mutect2, pindel, varscan2
- SLC6A9 | c.656A>G p.Y219C (on ENST00000360584 / NM_201649.4; = p.Y165C on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as COSV62212096; called by muse, mutect2, varscan2
- SLC7A2 | c.262G>A p.E88K (on ENST00000494857 / NM_001370338.1; = p.E128K on NM_003046.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757833276, COSV50267586; called by muse, mutect2, varscan2
- SLCO3A1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV59237201; called by muse, mutect2, varscan2
- SLCO5A1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52667989; called by muse, mutect2, varscan2
- SLF2 | c.3294A>C p.E1098D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53279751; called by mutect2, varscan2
- SLFN5 | c.1753A>C p.T585P | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55483469; called by muse, mutect2, varscan2
- SLITRK6 | c.356T>A p.I119N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749089230, COSV68391671; called by muse, mutect2, varscan2
- SMAD5 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs774538677, COSV72597681; called by muse, mutect2, varscan2
- SMARCC2 | c.2508G>T p.K836N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV57224895; called by muse, mutect2, varscan2
- SMC3 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV62422305; called by muse, mutect2, varscan2
- SMC5 | c.2935A>G p.S979G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV63195541; called by muse, mutect2, varscan2
- SMG5 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as rs779923631, COSV62437654; called by muse, mutect2, varscan2
- SNRPA | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs765984414, COSV54682568; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX32 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs368432434; called by muse, mutect2, varscan2
- SOX11 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58988019, COSV58988791; called by muse, mutect2, varscan2
- SPAG1 | c.1988+2C>T p.X663_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV52563401; called by muse, mutect2, varscan2
- SPART | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV62088405; called by muse, mutect2, varscan2
- SPECC1L | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); catalogued as COSV58661771; called by muse, mutect2, varscan2
- SPEG | c.3428G>A p.G1143D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56666578; called by muse, mutect2, varscan2
- SPG11 | c.2849del p.L950Wfs*13 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as CD166713; called by mutect2, pindel, varscan2
- SPIB | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as COSV99570094; called by muse, mutect2, varscan2
- SPRR2E | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV64203994, COSV64204055; called by muse, mutect2, varscan2
- SPRTN | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as COSV50479756; called by muse, mutect2, varscan2
- SPTA1 | c.4078C>T p.H1360Y | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63749094; called by muse, mutect2, varscan2
- SRGAP1 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs779089900, COSV61899027; called by muse, mutect2, varscan2
- ST18 | c.2093A>T p.K698M | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52509029; called by muse, mutect2, varscan2
- ST3GAL1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | PolyPhen benign (0.167); catalogued as COSV60616555; called by muse, mutect2, varscan2
- ST3GAL6 | c.901A>T p.M301L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV54584969; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | PolyPhen benign (0.014); catalogued as COSV50079947; called by muse, mutect2, varscan2
- STAM | c.1054A>G p.R352G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs782044601, COSV66325931; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT2 | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV58477364; called by muse, mutect2, varscan2
- STOX2 | c.491T>A p.I164K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV57856343; called by muse, mutect2, varscan2
- SUB1 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV54083463; called by muse, mutect2, varscan2
- SULF1 | c.223del p.A75Pfs*8 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs747316268, COSV52690552; called by pindel, varscan2
- SULT1E1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56948805; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | catalogued as rs747003550; called by mutect2, varscan2
- SUV39H1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551672, COSV61921377; called by muse, mutect2, varscan2
- SV2C | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59228913; called by muse, mutect2
- SVEP1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as rs760080901, COSV57047694; called by mutect2, varscan2
- SYNDIG1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs747730431, COSV65239625; called by muse, mutect2, varscan2
- SYNE1 | c.8170G>A p.A2724T (on ENST00000367255 / NM_182961.4; = p.A2731T on NM_033071.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs547324404, COSV54977906; called by muse, mutect2, varscan2
- SYNGAP1 | c.2756A>G p.Q919R | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.596); catalogued as COSV53386572; called by muse, mutect2, varscan2
- SYNJ2BP | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99832682; called by muse, mutect2, varscan2
- SYNM | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs369788122, COSV60374779; called by muse, mutect2, varscan2
- SYNPO | c.2434C>T p.R812C (on ENST00000394243 / NM_001166208.2; = p.R568C on NM_007286.6) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs768533306, COSV56942376; called by muse, mutect2, varscan2
- SYS1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | catalogued as rs374993970; called by muse, mutect2, varscan2
- TACC2 | c.5638G>A p.A1880T (on ENST00000334433; = p.A71T on NM_206861.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV57772599; called by muse, mutect2, varscan2
- TADA3 | c.1183T>G p.F395V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV57334463; called by muse, mutect2, varscan2
- TAGLN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1246995119, COSV99639176; called by muse, mutect2, varscan2
- TANC1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 31/52 reads (60%) | catalogued as rs761819583, COSV55083861; called by muse, mutect2, varscan2
- TBC1D23 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.141); catalogued as COSV61370305; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBCK | c.720+2T>C p.X240_splice (on ENST00000273980 / NM_001163436.4; = p.X177_splice on NM_033115.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as COSV56762651; called by muse, mutect2, varscan2
- TBXAS1 | c.1571del p.N524Mfs*29 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs748691839; called by mutect2, pindel, varscan2
- TBXT | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV51620052; called by muse, mutect2, varscan2
- TCEANC2 | c.335A>G p.E112G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV52371714; called by muse, mutect2
- TCF12 | c.546del p.V183Sfs*62 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs1352708150; called by mutect2, varscan2
- TCF12 | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); catalogued as rs796508804, COSV51023527; called by muse, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs748021112; called by mutect2, varscan2
- TCHH | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs576125673, COSV64277657; called by muse, mutect2, varscan2
- TDRD6 | c.5522C>T p.P1841L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV60174481; called by muse, mutect2, varscan2
- TEP1 | c.3026T>C p.V1009A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.482); catalogued as COSV52999927; called by muse, mutect2, varscan2
- TEP1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377196077; called by muse, mutect2, varscan2
- TERF2IP | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs754228214, COSV55614248; called by muse, mutect2, varscan2
- TET1 | c.5798C>T p.P1933L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs765929366, COSV65389461; called by muse, mutect2, varscan2
- THBS3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140469044; called by muse, mutect2, varscan2
- TIAL1 | c.395T>C p.M132T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.438); catalogued as COSV64843544; called by muse, mutect2, varscan2
- TIMM10 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57202024; called by muse, mutect2, varscan2
- TINAG | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV52514892; called by muse, mutect2, varscan2
- TJP2 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.865); catalogued as rs776190114, COSV55274060; called by mutect2, varscan2
- TM2D3 | c.677C>T p.T226M (on ENST00000333202 / NM_078474.3; = p.T200M on NM_025141.3) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754640606, COSV60881089; called by muse, mutect2, varscan2
- TMBIM4 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53970925; called by muse, mutect2, varscan2
- TMC3 | c.1736dup p.C580Mfs*80 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs1384203071; called by pindel, varscan2
- TMCC2 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV58006484; called by muse, mutect2
- TMED7-TICAM2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs371836337; called by muse, mutect2, varscan2
- TMEM18 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55245261; called by muse, mutect2, varscan2
- TMEM203 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58809055; called by muse, mutect2, varscan2
- TMEM63B | c.1895C>T p.T632M | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431296279, COSV52482364; called by muse, mutect2, varscan2
- TMPRSS15 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV53048922; called by muse, mutect2, varscan2
- TMPRSS3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as COSV52307577; called by muse, mutect2, varscan2
- TNFAIP2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs368740303; called by muse, mutect2, varscan2
- TNFSF10 | c.825del p.F275Lfs*5 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as COSV53842647; called by mutect2, pindel, varscan2
- TNR | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54912952; called by muse, mutect2, varscan2
- TOP2B | c.2462C>T p.A821V (on ENST00000264331 / NM_001330700.2; = p.A816V on NM_001068.3) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV51977095; called by muse, mutect2, varscan2
- TP63 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.353); catalogued as COSV53202068; called by muse, mutect2, varscan2
- TPP2 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65754904; called by muse, mutect2, varscan2
- TPR | c.5651A>G p.Q1884R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV66604974; called by muse, mutect2, varscan2
- TPT1 | c.293+1G>T p.X98_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58539250; called by muse, mutect2, varscan2
- TRA2B | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.84); catalogued as rs564623776, COSV52026368; called by muse, mutect2, varscan2
- TRANK1 | c.3986A>C p.Y1329S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57163819; called by muse, mutect2, varscan2
- TRAPPC2L | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs750672082, COSV51940470; called by muse, mutect2, varscan2
- TRAPPC8 | c.2037del p.F679Lfs*18 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs770561785; called by mutect2, varscan2
- TREH | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782231713, COSV50627086; called by muse, mutect2, varscan2
- TRIM22 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372042006, COSV66090849; called by muse, mutect2, varscan2
- TRIM25 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as COSV57545896; called by muse, mutect2, varscan2
- TRIM7 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774595436, COSV51247742; called by mutect2, varscan2
- TRPC7 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61463605; called by muse, mutect2
- TRRAP | c.4147A>G p.R1383G | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV62854176; called by muse, mutect2, varscan2
- TSGA10 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 67/103 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs758866582, COSV61822597; called by muse, mutect2, varscan2
- TSHZ1 | c.2987G>A p.S996N (on ENST00000580243 / NM_001308210.2; = p.S951N on NM_005786.6) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV59016845; called by muse, mutect2, varscan2
565 further variants in this file (213 protein-altering or splice-affecting, 325 silent, 27 other) are not listed here.
